Somatic mutation profile of tumor specimen BA3026D (aliquot aq-BA3026D) from BEATAML1.0 case 2452, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 53.9 years (19,677 days).
Specimen BA3026D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 036dd446-7ce7-4792-bfc6-913f1680a078.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2857D (Solid Tissue Normal), aliquot aq-BA2857D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8994ba54-7967-4d1c-9f0e-506f0d042a95

The open-access MAF lists 20 somatic variants for this specimen: 11 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 7, Frame Shift Ins 2, Frame Shift Del 1, Intron 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNMT3A | c.2645G>A p.R882H | Missense Mutation (SNP) | VAF 26/56 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.067); catalogued as rs147001633, COSV53036153, COSV53040144, COSV53040431; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 65/75 reads (87%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- COL3A1 | c.2866C>T p.R956W | Missense Mutation (SNP) | VAF 80/148 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs866738225; called by muse, mutect2, varscan2
- DNAH3 | c.6452A>T p.Y2151F | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs1459614181; called by muse, varscan2
- MYLK | c.4843G>A p.A1615T | Missense Mutation (SNP) | VAF 92/304 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.078); catalogued as rs1185016724; called by muse, mutect2
- PCDHB13 | c.1808C>T p.S603L | Missense Mutation (SNP) | VAF 74/220 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs782296190, COSV53396206; called by muse, mutect2, varscan2
- PRKCZ | c.164C>T p.P55L | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT tolerated (0.49); PolyPhen benign (0.031); catalogued as rs759002098; called by muse, varscan2
- PIKFYVE | c.5294dup p.L1765Ffs*6 | Frame Shift Ins (INS) | VAF 103/285 reads (36%) | called by mutect2, pindel, varscan2
- PROX1 | c.1337del p.N446Tfs*43 | Frame Shift Del (DEL) | VAF 10/22 reads (45%) | called by mutect2, varscan2
- STAG2 | c.385_385+1insAA p.G129Efs*17 | Frame Shift Ins (INS) | VAF 55/144 reads (38%) | called by mutect2, pindel, varscan2
- ZNF354C | c.151C>A p.L51M | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.22); called by muse, mutect2
- COP1 | c.1935T>C p.F645= | Silent (SNP) | VAF 41/92 reads (45%) | catalogued as rs1455604442; called by muse, mutect2, varscan2
- CPXM2 | c.294G>A p.P98= | Silent (SNP) | VAF 17/35 reads (49%) | catalogued as rs1479214611; called by muse, mutect2, varscan2
- CSMD1 | c.7911G>A p.T2637= (on ENST00000520002; = p.T2636= on NM_033225.6) | Silent (SNP) | VAF 70/131 reads (53%) | catalogued as rs374916113, COSV59300184, COSV59301955; called by muse, varscan2
- HCN1 | c.906C>T p.I302= | Silent (SNP) | VAF 76/147 reads (52%) | catalogued as rs756704380, COSV57494287; called by muse, mutect2, varscan2
- LAMC2 | c.3264C>G p.A1088= | Silent (SNP) | VAF 89/220 reads (40%) | called by muse, mutect2, varscan2
- NFASC | c.3684G>A p.E1228= (on ENST00000339876 / NM_001378329.1; = p.E1157= on NM_015090.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 89/211 reads (42%) | catalogued as rs770703769; called by muse, mutect2, varscan2
- SHROOM2 | c.3792G>A p.T1264= | Silent (SNP) | VAF 12/18 reads (67%) | catalogued as rs1178300256; called by muse, mutect2, varscan2
- DDX41 | c.*170C>T | 3'UTR (SNP) | VAF 25/60 reads (42%) | called by muse, mutect2, varscan2
- LDAH | c.298+953G>T | Intron (SNP) | VAF 4/25 reads (16%) | called by muse, mutect2
